Somatic mutation profile of tumor specimen MP2PRT-PAUMSI-TMP1-A (aliquot MP2PRT-PAUMSI-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUMSI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,730 days).
Specimen MP2PRT-PAUMSI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0af7ccb3-3d3d-4583-9116-5446993bc919.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMSI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMSI-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/706c36bb-d28b-4a28-9bfa-0ec1fc141d11

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Translation Start Site 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP31 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs768829713, COSV99957427; called by muse, mutect2, varscan2
- EPS15L1 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751223293, COSV50167643; called by muse, mutect2, varscan2
- FMN1 | c.3593G>A p.R1198Q (on ENST00000616417 / NM_001277313.2; = p.R975Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57925717; called by muse, mutect2, varscan2
- ITGAE | c.3526G>C p.E1176Q | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.079); catalogued as COSV53992556; called by muse, varscan2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 103/280 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by muse, mutect2, varscan2
- OR10G4 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs536792742, COSV100304745; called by muse, mutect2
- PAX7 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 143/330 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748780342, COSV64751584; called by muse, mutect2, varscan2
- PEBP4 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1349303754; called by muse, mutect2
- PRDM15 | c.3268G>A p.V1090M | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs1165875283, COSV99521147; called by muse, mutect2, varscan2
- PSMG1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as rs748645572; called by muse, mutect2, varscan2
- VNN1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs764072318, COSV63389944; called by muse, mutect2
- CADPS2 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 116/273 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FUT2 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- MAOB | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 16/558 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRKG1 | c.1232A>T p.H411L | Missense Mutation (SNP) | VAF 17/409 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- BCAN | c.1905C>T p.S635= | Silent (SNP) | VAF 151/420 reads (36%) | catalogued as rs761210707, COSV100228089; called by muse, varscan2
- CYP4V2 | c.651C>T p.S217= | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as rs1183911113; called by muse, mutect2, varscan2
- DSCAML1 | c.2775C>T p.F925= (on ENST00000321322; = p.F865= on NM_020693.4) | Silent (SNP) | VAF 16/504 reads (3%) | catalogued as rs1449743788; called by muse, mutect2
- SERTM1 | c.246C>T p.D82= | Silent (SNP) | VAF 181/389 reads (47%) | catalogued as rs751992309, COSV59376789; called by muse, mutect2, varscan2
- SLITRK4 | c.*417C>T | 3'UTR (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26670370 C>T | 5'Flank (SNP) | VAF 15/427 reads (4%) | called by muse, mutect2
